Somatic mutation profile of tumor specimen C3N-08896-01 (aliquot CPT0495300006) from CPTAC case C3N-08896, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 56.9 years (20,765 days).
Specimen C3N-08896-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c91670dc-1a49-4c4a-9759-8fa88109f6dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-08896-31 (Blood Derived Normal), aliquot CPT0495360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01f6f1d6-2538-42a8-b06a-4bf38e943ce1

The open-access MAF lists 99 somatic variants for this specimen: 74 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 21, Frame Shift Ins 3, Nonsense Mutation 2, Intron 2, 5'UTR 1, Frame Shift Del 1, Splice Site 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.13057G>A p.A4353T | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.155); catalogued as rs375501382; called by muse, mutect2, varscan2
- ALS2CL | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs142502930; called by muse, varscan2
- B9D2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.441); catalogued as rs1224741304; called by muse, mutect2, varscan2
- CELA2B | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs535515233, COSV62747409; called by muse, mutect2, varscan2
- CLDN9 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 96/449 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs751354671; called by muse, mutect2, varscan2
- CLSTN3 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs1393171977, COSV56934143; called by muse, varscan2
- COL4A2 | c.2398G>A p.G800R | Missense Mutation (SNP) | VAF 57/553 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867981304, COSV64626329; called by muse, mutect2, varscan2
- CXXC1 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1175966411; called by muse, mutect2, varscan2
- DNAJB6 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51101089; called by muse, mutect2, varscan2
- GPR20 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 91/660 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs779977490, COSV66683999; called by muse, mutect2, varscan2
- GRIK2 | c.2546dup p.N849Kfs*11 | Frame Shift Ins (INS) | VAF 30/142 reads (21%) | catalogued as rs760757380; called by mutect2, varscan2
- HMGCS2 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs755313968; called by muse, mutect2, varscan2
- MYADML2 | c.351dup p.E118Rfs*68 | Frame Shift Ins (INS) | VAF 97/457 reads (21%) | catalogued as rs993221819; called by mutect2, pindel, varscan2
- NPR1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 127/490 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs758993261; called by muse, mutect2, varscan2
- OR52J3 | c.679T>A p.F227I | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100984911; called by muse, mutect2, varscan2
- PCDH17 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 125/377 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64971957; called by muse, mutect2, varscan2
- PCDHB10 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 118/639 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.046); catalogued as COSV99504555; called by muse, varscan2
- PCDHGA10 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 96/556 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as COSV53988534; called by muse, mutect2, varscan2
- PCDHGB4 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 82/508 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1388057704, COSV53910946; called by muse, mutect2, varscan2
- PDSS1 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763165754; called by muse, mutect2, varscan2
- PLCH1 | c.1772G>A p.R591Q (on ENST00000340059 / NM_001130960.2; = p.R603Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.234); catalogued as rs769302426, COSV58188123; called by muse, mutect2, varscan2
- PLEC | c.5054C>T p.A1685V (on ENST00000322810 / NM_201380.4; = p.A1575V on NM_000445.5) | Missense Mutation (SNP) | VAF 206/707 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs533788232; called by muse, mutect2, varscan2
- PLEKHG4B | c.1244G>A p.R415Q (on ENST00000283426; = p.R771Q on NM_052909.5) | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs777091719, COSV52043481; called by muse, mutect2, varscan2
- PLXNA4 | c.4910G>A p.R1637Q | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs753325197, COSV58127821; called by muse, mutect2, varscan2
- PPL | c.5002G>A p.E1668K | Missense Mutation (SNP) | VAF 92/392 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs532013525, COSV99277833; called by muse, mutect2, varscan2
- PRMT8 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as rs1290294414, COSV54211906; called by muse, mutect2, varscan2
- SLC22A31 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 97/422 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs559452735; called by muse, mutect2, varscan2
- SLC27A6 | c.696del p.A233Qfs*3 | Frame Shift Del (DEL) | VAF 36/222 reads (16%) | catalogued as rs1400827147; called by mutect2, pindel, varscan2
- SLITRK4 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs782772067, COSV62026229; called by muse, mutect2, varscan2
- SOX2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 116/612 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs762331271; called by muse, mutect2, varscan2
- ST6GAL2 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 79/391 reads (20%) | PolyPhen benign (0.427); catalogued as rs758618457; called by muse, mutect2, varscan2
- TEX10 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV66518025; called by muse, mutect2, varscan2
- TSPYL6 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 57/436 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs770223555, COSV57812026, COSV57814357; called by muse, mutect2, varscan2
- USP28 | c.3008T>A p.I1003N | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99134548; called by muse, mutect2, varscan2
- ZC3HC1 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as rs374729873; called by muse, mutect2, varscan2
- ZER1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 68/356 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as rs778212361, COSV52568848, COSV52569337; called by muse, mutect2, varscan2
- ZNF775 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 84/515 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774580244, COSV61613851; called by muse, mutect2, varscan2
- ZSCAN1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 67/461 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1568606661, COSV56606744; called by muse, mutect2, varscan2
- ARL4D | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ATP1A3 | c.1397C>A p.S466Y (on ENST00000545399 / NM_001256214.2; = p.S453Y on NM_152296.5) | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- BEST2 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 46/800 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2
- C19orf81 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 83/415 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CACNA2D4 | c.635A>T p.N212I | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALML5 | c.172_183del p.S58_D61del | In Frame Del (DEL) | VAF 50/335 reads (15%) | called by mutect2, pindel, varscan2
- DUSP15 | c.244C>T p.L82F (on ENST00000278979 / NM_001320479.1; = p.L85F on NM_080611.4) | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUSP15 | c.243C>A p.C81* (on ENST00000278979 / NM_001320479.1; = p.C84* on NM_080611.4) | Nonsense Mutation (SNP) | VAF 29/210 reads (14%) | called by muse, mutect2, varscan2
- FOXI2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 124/504 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GALNT2 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN2B | c.2597G>T p.R866I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HS6ST2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 90/413 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPKC | c.1291A>C p.K431Q | Missense Mutation (SNP) | VAF 16/371 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ITPR3 | c.5900T>C p.I1967T | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- KLC4 | c.1810-12_1811del p.X604_splice | Splice Site (DEL) | VAF 36/262 reads (14%) | called by mutect2, pindel, varscan2
- LIG3 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MID1IP1 | c.499_500insGT p.I167Sfs*77 | Frame Shift Ins (INS) | VAF 68/351 reads (19%) | called by mutect2, pindel, varscan2
- MTX1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 136/444 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NDRG4 | c.658C>T p.P220S (on ENST00000570248 / NM_001378344.1; = p.P252S on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR2A1 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 70/728 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- OR2T12 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 23/674 reads (3%) | called by muse, mutect2
- OR5AN1 | c.848T>G p.I283S | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB8 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 76/1036 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PDE6A | c.1070G>T p.C357F | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PGBD1 | c.2348C>A p.P783Q | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2
- PIWIL1 | c.411C>A p.N137K | Missense Mutation (SNP) | VAF 68/399 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0); called by mutect2, varscan2
- RIOX1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SCN3B | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRCIN1 | c.977G>A p.R326Q (on ENST00000621492; = p.R292Q on NM_025248.3) | Missense Mutation (SNP) | VAF 107/660 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TMEM147 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM248 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSSK3 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- UBASH3B | c.1113G>A p.Q371= | Splice Region (SNP) | VAF 38/178 reads (21%) | called by muse, mutect2, varscan2
- UNCX | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNT5A | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 91/471 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZCCHC8 | c.1595A>G p.E532G | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- AGBL5 | c.483C>T p.Y161= | Silent (SNP) | VAF 59/445 reads (13%) | catalogued as COSV100549092; called by muse, mutect2, varscan2
- BICC1 | c.2100C>T p.R700= | Silent (SNP) | VAF 64/322 reads (20%) | catalogued as rs537675644, COSV54065048; called by muse, mutect2, varscan2
- CNNM2 | c.585C>G p.L195= | Silent (SNP) | VAF 98/535 reads (18%) | catalogued as rs1223626683; called by muse, mutect2, varscan2
- CNTNAP3 | c.1887G>A p.A629= | Silent (SNP) | VAF 47/272 reads (17%) | catalogued as COSV52670721; called by muse, mutect2, varscan2
- COL6A3 | c.1119C>T p.S373= | Silent (SNP) | VAF 154/493 reads (31%) | catalogued as rs754202674, COSV55089167, COSV99799598; called by muse, mutect2, varscan2
- EPS15L1 | c.2277C>T p.S759= | Silent (SNP) | VAF 16/338 reads (5%) | catalogued as rs776960200; called by muse, mutect2
- GSDMD | c.828G>T p.G276= | Silent (SNP) | VAF 26/434 reads (6%) | called by muse, mutect2
- IGLV4-3 | c.363C>T p.V121= | Silent (SNP) | VAF 34/186 reads (18%) | catalogued as rs763300944; called by muse, mutect2, varscan2
- KLF8 | c.960G>A p.E320= | Silent (SNP) | VAF 86/334 reads (26%) | called by muse, mutect2, varscan2
- MOGAT3 | c.924C>A p.V308= | Silent (SNP) | VAF 72/480 reads (15%) | called by mutect2, varscan2
- NFATC1 | c.147C>A p.S49= | Silent (SNP) | VAF 175/466 reads (38%) | catalogued as COSV99500597; called by muse, mutect2, varscan2
- PRKCE | c.1326C>T p.D442= | Silent (SNP) | VAF 76/326 reads (23%) | catalogued as rs371646070; called by muse, mutect2, varscan2
- PTCHD3 | c.135G>A p.P45= | Silent (SNP) | VAF 26/429 reads (6%) | catalogued as rs926783992; called by muse, mutect2
- RBMXL2 | c.345C>T p.G115= | Silent (SNP) | VAF 85/457 reads (19%) | catalogued as rs1238854569; called by muse, mutect2, varscan2
- ROBO2 | c.228C>T p.D76= | Silent (SNP) | VAF 62/361 reads (17%) | catalogued as rs1005805298, COSV100164224; called by muse, mutect2, varscan2
- SLITRK1 | c.1398T>C p.T466= | Silent (SNP) | VAF 106/411 reads (26%) | called by muse, mutect2, varscan2
- TMEM139 | c.111C>T p.P37= | Silent (SNP) | VAF 68/354 reads (19%) | catalogued as rs954620689, COSV60082323; called by muse, mutect2, varscan2
- TMEM151B | c.681G>A p.A227= | Silent (SNP) | VAF 95/462 reads (21%) | catalogued as rs1365278509; called by muse, mutect2, varscan2
- TMEM200C | c.210G>A p.A70= | Silent (SNP) | VAF 58/491 reads (12%) | catalogued as COSV101274875; called by muse, mutect2, varscan2
- WNT6 | c.870G>A p.S290= | Silent (SNP) | VAF 36/672 reads (5%) | catalogued as rs1481336056; called by muse, mutect2
- ZNF518B | c.1929T>C p.S643= | Silent (SNP) | VAF 70/311 reads (23%) | called by muse, mutect2, varscan2
- AC004837.1 | n.101G>C | RNA (SNP) | VAF 98/539 reads (18%) | called by muse, mutect2, varscan2
- CYHR1 | c.246+1930_246+1950del | Intron (DEL) | VAF 38/180 reads (21%) | called by mutect2, varscan2
- DST | c.4297-3711G>A | Intron (SNP) | VAF 58/362 reads (16%) | catalogued as rs202086197, COSV99757494; called by muse, mutect2, varscan2
- NRBP1 | c.-62G>C | 5'UTR (SNP) | VAF 80/452 reads (18%) | catalogued as rs954349168; called by muse, mutect2, varscan2
